Surgical pathology report (de-identified scan), TCGA case TCGA-B0-5713, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site University of Pittsburgh, specimen TCGA-B0-5713-01A (Primary Tumor).

PATIENT HISTORY:

Not given.

PRE-OP DIAGNOSIS: Left renal cancer.

POST-OP DIAGNOSIS: Same.

PROCEDURE: Left laparoscopic nephrectomy.

FINAL DIAGNOSIS:

KIDNEY, LEFT, LAPAROSCOPIC NEPHRECTOMY -

- A. RENAL CELL CARCINOMA, CONVENTIONAL (CLEAR) CELL TYPE.
- B. FUHRMAN'S NUCLEAR GRADE IS 3 of 4.
- C. THE GREATEST DIAMETER OF THE NEOPLASM IS 7.2 CM.
- D. THE NEOPLASM IS CONFINED WITHIN THE RENAL CAPSULE.
- E. TUMOR INVADES INTO THE RENAL VEIN WITH INVOLVEMENT OF THE VESSEL WALL.
- F. ALL SURGICAL MARGINS ARE FREE OF THE NEOPLASM.
- G. THE NON-NEOPLASTIC KIDNEY IS UNREMARKABLE.
- H. THE ADRENAL GLAND IS NOT SUBMITTED.
- I. TNM STAGE: pT3b NX MX.

MICROSCOPIC:

SYNOPTIC DATA - PRIMARY KIDNEY TUMORS

SPECIMEN TYPE:	Other: Laparoscopic nephrectomy
LATERALITY:	Left
TUMOR SITE:	Lower pole
FOCALITY:	Unifocal
TUMOR SIZE:	Greatest dimension: 7.2 cm
MACROSCOPIC EXTENT OF TUMOR:	Tumor limited to kidney
HISTOLOGIC TYPE:	Clear cell (conventional) renal carcinoma
HISTOLOGIC GRADE (Fuhrman Nuclear Grade):	G3
PATHOLOGIC STAGING (pTNM):	pT3b
	pNX
	Number of regional lymph nodes examined: 0
	pMX
MARGINS:	Margins uninvolved by invasive carcinoma
ADRENAL GLAND:	Not present
VENOUS (LARGE VESSEL) INVASION (V):	Present
LYMPHATIC (SMALL VESSEL) INVASION (L):	Absent
ADDITIONAL PATHOLOGIC FINDINGS:	None identified

Source: NCI Genomic Data Commons file 4742266f-7ed1-49ff-997d-435101a7b1c9 (TCGA-B0-5713.F83B6A91-615B-4F67-BEDA-F982B7DDCB94.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).